Somatic mutation profile of tumor specimen TARGET-10-PARDUM-09A (aliquot TARGET-10-PARDUM-09A-01D) from TARGET case TARGET-10-PARDUM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,104 days).
Specimen TARGET-10-PARDUM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 215f76a2-6e28-4e69-b466-4d8de162fbab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDUM-10A (Blood Derived Normal), aliquot TARGET-10-PARDUM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21b60db3-0520-4709-8165-e35dbd6da5b5

The open-access MAF lists 22 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 7, Nonsense Mutation 2, 5'Flank 2, RNA 1, Frame Shift Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>A p.N676K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.2533A>G p.R845G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV54053469; called by muse, mutect2, varscan2
- GDF5 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs767571173, COSV65502152; called by muse, mutect2, varscan2
- IRS1 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.235); catalogued as rs141295519; called by muse, mutect2, varscan2
- PCLO | c.4828C>T p.R1610* | Nonsense Mutation (SNP) | VAF 17/159 reads (11%) | catalogued as COSV61627815, COSV61634849; called by muse, mutect2, varscan2
- QRFPR | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as rs767056594, COSV57676046; called by muse, mutect2, varscan2
- TRIM29 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as COSV100531812; called by muse, mutect2, varscan2
- PAX5 | c.629dup p.N210Kfs*33 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- SPTLC1 | c.927T>A p.N309K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SYNPO2 | c.2947G>C p.D983H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ENTPD8 | c.162G>A p.T54= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as rs199873802; called by muse, mutect2, varscan2
- GTPBP4 | c.882G>A p.K294= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1484136707, COSV62551856; called by muse, mutect2
- JAG2 | c.3051G>A p.A1017= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs761428165; called by muse, mutect2, varscan2
- LMX1A | c.291C>T p.C97= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- NLRP4 | c.2262G>A p.T754= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs369543357; called by muse, mutect2, varscan2
- PHLPP1 | c.4134C>T p.D1378= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs368103591; called by muse, mutect2, varscan2
- SSC5D | c.3264C>T p.P1088= | Silent (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- FAM87A | n.1876G>A | RNA (SNP) | VAF 12/36 reads (33%) | catalogued as rs1343387698; called by muse, mutect2, varscan2
- MAGIX | c.196+107C>T | Intron (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- MIR29A | chr7:130876894 G>A | 5'Flank (SNP) | VAF 2/16 reads (13%) | called by muse, mutect2
- MIR29A | chr7:130876895 G>A | 5'Flank (SNP) | VAF 2/17 reads (12%) | called by muse, mutect2
- MPPED2 | c.*117G>T | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
